Surgical pathology report (de-identified scan), TCGA case TCGA-Q2-A5QZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q2-A5QZ-01A (Primary Tumor).

[page 1 of 3]
MEDICAL CENTER
LABORATORY

PAGE:1

Specimen Inquiry

PATIENT:

ACCT #:

LOC:

U#:

AGE/SX: /F

SPEC #:

CLINICAL HISTORY:

RIGHT RENAL MASS

SPECIMEN/PROCEDURE:

1. KIDNEY - RIGHT

IMPRESSION:

RIGHT KIDNEY, RIGHT NEPHRECTOMY:

- . Papillary renal cell carcinoma, type II, Fuhrman nuclear grade 3, with focal renal capsule invasion. (Please see tumor checklist).
- . Margins of resection, free of tumor.

KIDNEY: NEPHRECTOMY, PARTIAL OR RADICAL CASE SUMMARY

PROCEDURE

Radical nephrectomy

SPECIMEN LATERALITY

Right

TUMOR SITE

Middle

TUMOR SIZE (largest tumor if multiple)

Greatest dimension: 5.3 cm

Additional dimensions: 5.2 x 4.8 cm

TUMOR FOCALITY

Unifocal

MACROSCOPIC EXTENT OF TUMOR

Tumor abutting the renal capsule with possible extension into perinephric tissue (beyond renal capsule)

HISTOLOGIC TYPE

Papillary renal cell carcinoma

SARCOMATOID FEATURES

Not identified

TUMOR NECROSIS (any amount)

Present

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE)

G3: Nuclei very irregular, approximately 20 m; nucleoli large and prominent

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site (R) Kidney NOS
C64.9
JW 4/12/13

[page 2 of 3]
SPEC #:

IMPRESSION: (continued)**MICROSCOPIC TUMOR EXTENSION**

Tumor extension into perinephric tissue (beyond renal capsule)

MARGINS

Margins uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION(excluding renal vein and its muscle containing segmental branches and inferior vena cava)
Absent**PATHOLOGIC STAGING (pTNM)****PRIMARY TUMOR (pT)**

pT3a: Tumor invades perirenal and/or renal sinus fat but not beyond Gerota's fascia

REGIONAL LYMPH NODES (pN)

No nodes submitted or found

DISTANT METASTASIS (pM)

Not applicable

PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY

Significant pathologic alterations

Tubulointerstitial disease (specify type): Chronic interstitial nephritis

Pathologic TNM (AJCC 7th edition): pT3a NX M

COMMENT:

Case reviewed by

SPECIAL STAINS/PROCEDURES:

Immunohistochemical stains were performed with appropriate positive and negative controls.

Pancytokeratin:

Positive in tumor cells with likely perinephric tissue invasion.

CD31:

No definite evidence of intravascular tumor invasion seen.

GROSS DESCRIPTION:

1. Received fresh, labeled with the patient's name, medical record number and "right kidney" is a 302 gram right radical nephrectomy specimen including kidney (9.5 x 7.8 x 6.8 cm) and surrounding perirenal fat measuring in thickness from 1.0 to 2.0 cm. No adrenal gland is identified. Extending from the renal pelvis is a ureter (2.5 cm in length by 0.3 cm in diameter), renal vein (0.5 cm in length by 0.3 cm in diameter), and renal artery (1 cm in diameter by 0.4 cm in diameter). There is a 5.3 x 5.2 x 4.8 cm pale-white tumor with

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
GROSS DESCRIPTION: (continued)

focal areas of hemorrhage, located in the mid-portion of the kidney. The tumor abutts the perirenal fat without penetrating the renal capsule. The tumor also does not involve renal sinus fat or the renal pelvis. The remainder of the renal cortex is tan/brown with a well-defined cortical medullary junction. The pelvis and calyces are covered by smooth glistening mucosa. The adipose tissue is thinly sectioned and no lymphnodes are identified.

A portion of the tumor is taken for TCGA research.
Devitalization time:
Freeze time:

Ink code:
black-outer surface of specimen.

CASSETTE SUMMARY:

CASSETTE 1A: renal artery, vein and ureter
CASSETTE 1B-1E: tumor abutting perirenal fat
CASSETTE 1G,1H: tumor adjacent to renal sinus\
CASSETTE 1J: tumor with kidney parenchyma
CASSETTE 1K: normal kidney
CASSETTE 1L,1M: additional sections of tumor with kidney parenchyma

Entered

COPIES TO:

CPT Codes:

IHC CD31-88342, KIDNEY, PART/TTL RESECTION TUMOR/88307, IHC KERATIN COCKTAIL-88342,
NEG MAB CONTROL/2

ICD9 Codes:

189.0

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by:

Physicians

** END OF REPORT **

Criteria	1/31/13	Yes	No
Dual, Synchronous Primary Nodules			

Source: NCI Genomic Data Commons file 8cce036a-379d-4d6c-8cac-da7b1458d0c2 (TCGA-Q2-A5QZ.5CDCBD3A-060E-4F28-9328-F1367B8572F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).